Gene-level copy-number profile of tumor specimen C3L-03262-01 (profiled together with C3L-03262-03) from CPTAC case C3L-03262, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.3 years (24,929 days).
Specimen C3L-03262-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69b28b5e-fd3f-4e27-85e9-cb93814d7cc0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03262-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/b5ea37dc-2390-4f69-bdf6-61d9ce2e70fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14; copy number 2: 56,804; copy number 3: 1,002; copy number 4: 488; copy number 5: 91.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 91 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,436,359–248,919,946, 31 genes, copy number 5: OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 4–5): PCAT1.
- chr8:126,766,196–128,564,679, 24 genes, copy number 5: AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,291,275, 3 genes, copy number 5: AC103833.2, AC103833.1, RN7SKP206.
- chr8:130,052,104–132,013,642, 15 genes, copy number 5: ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A.
- chr8:143,857,324–144,118,328, 17 genes, copy number 5: EPPK1, PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
